Somatic mutation profile of tumor specimen TCGA-CN-A63T-01A (aliquot TCGA-CN-A63T-01A-11D-A28R-08) from TCGA case TCGA-CN-A63T, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 60.8 years (22,201 days).
Specimen TCGA-CN-A63T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa857b32-7a2e-4dea-b964-a55f025f1bd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A63T-10A (Blood Derived Normal), aliquot TCGA-CN-A63T-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4fc44e5-180a-41f7-98d1-aa76e38f08de

The open-access MAF lists 257 somatic variants for this specimen: 199 protein-altering or splice-affecting, 54 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 54, Nonsense Mutation 13, Frame Shift Del 6, Splice Site 5, RNA 3, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.6463+1G>A p.X2155_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as rs398124381, COSV100728439, COSV61770653; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 36/74 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.5269C>G p.P1757A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1477513571, COSV100933019, COSV100933028, COSV64673636; called by muse, mutect2, varscan2
- AC104452.1 | c.1254G>C p.M418I | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV99648591; called by muse, mutect2, varscan2
- ADAM28 | c.1786G>C p.E596Q | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV99737808; called by muse, mutect2, varscan2
- ADAMTS3 | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99710248; called by muse, mutect2, varscan2
- ADGRV1 | c.18304G>A p.A6102T | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); catalogued as COSV67988700; called by muse, mutect2, varscan2
- AFF3 | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs756174447, COSV100417788; called by muse, mutect2, varscan2
- AGO3 | c.1748A>G p.Q583R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.158); catalogued as COSV99867997; called by muse, mutect2, varscan2
- ALMS1 | c.1514A>C p.D505A | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100041181; called by muse, mutect2, varscan2
- ALPI | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV99785674; called by muse, mutect2, varscan2
- ANK2 | c.3307G>T p.D1103Y | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52150308, COSV52182396; called by muse, mutect2, varscan2
- ANKH | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1180838297, COSV52485075; called by muse, mutect2, varscan2
- ANO5 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100201416; called by muse, mutect2, varscan2
- ASCL1 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901895, COSV99901983; called by muse, mutect2, varscan2
- ASH1L | c.7466A>G p.D2489G (on ENST00000368346 / NM_001366177.2; = p.D2484G on NM_018489.3) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV100853119; called by muse, mutect2, varscan2
- ASPM | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99038507; called by muse, mutect2, varscan2
- ATP10A | c.2104G>T p.A702S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761040930, COSV100790883; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2453A>G p.Y818C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100022666; called by muse, mutect2, varscan2
- ATP6V1H | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484260251, COSV100778606; called by muse, mutect2, varscan2
- ATR | c.1645A>T p.S549C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100637679, COSV63384593; called by muse, mutect2, varscan2
- BMP5 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748959947, COSV63705821; called by muse, mutect2, varscan2
- BMPR1B | c.247-1G>T p.X83_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | catalogued as COSV52781631, COSV99215357; called by muse, mutect2, varscan2
- BZW1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV100729825; called by muse, mutect2, varscan2
- C10orf53 | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100934839; called by muse, mutect2, varscan2
- CC2D2B | c.35A>G p.K12R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs753045522, COSV100729299; called by muse, mutect2
- CCDC102A | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV99264802; called by muse, mutect2, varscan2
- CCN1 | c.674A>C p.Q225P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101486114; called by muse, mutect2, varscan2
- CEACAM1 | c.1425C>A p.N475K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV99362156; called by muse, mutect2, varscan2
- CFAP47 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV99934415; called by muse, mutect2, varscan2
- CFAP47 | c.1679T>A p.V560E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.956); catalogued as COSV99934417; called by muse, mutect2, varscan2
- CFTR | c.400A>G p.R134G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99134130; called by muse, mutect2, varscan2
- CNTN6 | c.2431C>G p.L811V | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100610092; called by muse, mutect2, varscan2
- COL1A2 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99798644; called by muse, mutect2, varscan2
- COL4A3 | c.1947T>G p.S649R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV101169952; called by muse, mutect2, varscan2
- COL4A4 | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.824); catalogued as COSV100306237, COSV100307541; called by muse, mutect2
- CPA3 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763942534, COSV99935968; called by muse, mutect2, varscan2
- CRACDL | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV101194008, COSV67406304; called by muse, mutect2, varscan2
- CSMD3 | c.6836G>A p.C2279Y (on ENST00000297405 / NM_001363185.1; = p.C2175Y on NM_052900.3) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99825308; called by muse, varscan2
- CSMD3 | c.6758G>A p.G2253E (on ENST00000297405 / NM_001363185.1; = p.G2149E on NM_052900.3) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99825311; called by muse, varscan2
- CSMD3 | c.5539C>T p.Q1847* (on ENST00000297405 / NM_001363185.1; = p.Q1743* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 49/127 reads (39%) | catalogued as COSV52315795, COSV99825313; called by muse, mutect2, varscan2
- CSNK1A1L | c.310T>C p.C104R | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1281438102, COSV101131067; called by muse, mutect2, varscan2
- CTNNA2 | c.2379C>A p.S793R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100559514; called by muse, mutect2, varscan2
- CTTNBP2 | c.4816G>A p.V1606I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as rs374415476, COSV99353085; called by muse, mutect2, varscan2
- DDX27 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV100874638; called by muse, mutect2, varscan2
- DDX60 | c.4475G>T p.G1492V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV101190250; called by muse, mutect2, varscan2
- DGKG | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV99402492; called by muse, mutect2, varscan2
- DICER1 | c.2739G>C p.K913N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV100601769; called by muse, mutect2, varscan2
- DMRTC2 | c.630C>A p.G210= | Splice Region (SNP) | VAF 41/161 reads (25%) | catalogued as COSV99523301; called by muse, mutect2, varscan2
- DNAH11 | c.2801C>A p.T934K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100177240; called by muse, mutect2, varscan2
- DNAJC1 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100981076; called by muse, mutect2, varscan2
- DNMBP | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as COSV100143106; called by muse, mutect2, varscan2
- DPP3 | c.1498A>T p.S500C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs201439382, COSV100855430; called by muse, mutect2, varscan2
- DST | c.4907C>A p.A1636D | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.099); catalogued as COSV99751296; called by muse, mutect2, varscan2
- DUSP5 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100851818; called by muse, mutect2, varscan2
- EPHA2 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626024; called by muse, mutect2, varscan2
- ERICH1 | c.712A>T p.S238C | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV100032189; called by muse, mutect2, varscan2
- EVA1A | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52063146, COSV99285308; called by muse, mutect2, varscan2
- EXD2 | c.1351A>T p.N451Y (on ENST00000312994 / NM_001193362.1; = p.N326Y on NM_018199.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100473758; called by muse, mutect2, varscan2
- EYS | c.938G>T p.S313I | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100675679; called by muse, mutect2, varscan2
- EYS | c.113C>G p.S38* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as rs1288767318, COSV100675681; called by muse, mutect2, varscan2
- F13A1 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99342236; called by muse, mutect2, varscan2
- FAM163B | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs773430083, COSV100618902; called by muse, mutect2
- FAM50B | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100976508; called by muse, mutect2, varscan2
- FBN3 | c.6043_6044del p.S2015Ffs*7 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | catalogued as rs1353564633; called by pindel, varscan2
- FBXO39 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); catalogued as COSV100386124; called by muse, mutect2, varscan2
- FBXW11 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99439772; called by muse, mutect2, varscan2
- FER | c.1927G>T p.G643C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99811656; called by muse, mutect2
- FTO | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV99193081; called by muse, mutect2, varscan2
- GAK | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100033163; called by muse, mutect2, varscan2
- GAS2L2 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs782017848; called by muse, mutect2, varscan2
- GGT1 | c.1706A>T p.Y569F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as COSV99958578; called by mutect2, varscan2
- GRIA1 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370642711; called by muse, mutect2, varscan2
- GUCY1A1 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 20/183 reads (11%) | catalogued as rs749771282, COSV56650537; called by muse, mutect2
- H1-5 | c.109A>C p.K37Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100137697; called by muse, mutect2, varscan2
- H2AC12 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.3); catalogued as rs150434841; called by muse, mutect2, varscan2
- IGSF9B | c.1187C>A p.T396N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100317006; called by muse, mutect2, varscan2
- IL17REL | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100377292; called by muse, mutect2, varscan2
- IL31RA | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV100732452; called by muse, mutect2, varscan2
- ITGA8 | c.1523A>T p.Q508L | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100958878; called by muse, mutect2, varscan2
- KCNA6 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99768340; called by muse, mutect2, varscan2
- KIAA0895 | c.419C>T p.S140F (on ENST00000297063 / NM_001100425.2; = p.S89F on NM_015314.3) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1474786729, COSV51714035; called by muse, mutect2, varscan2
- KIAA1549 | c.5234A>G p.N1745S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs376508722; called by muse, mutect2, varscan2
- KRT82 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99233386; called by muse, mutect2, varscan2
- KRTAP15-1 | c.76T>C p.Y26H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100481608; called by muse, mutect2, varscan2
- LEPR | c.3323G>T p.C1108F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.116); catalogued as COSV100847879; called by muse, mutect2, varscan2
- LHFPL3 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs767910543, COSV67813165; called by muse, mutect2, varscan2
- LRP2 | c.5869G>T p.V1957L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV99786594; called by muse, mutect2, varscan2
- LRP6 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99742400; called by muse, mutect2, varscan2
- LSM4 | c.145-2A>G p.X49_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as rs112426584, COSV99416826; called by muse, mutect2, varscan2
- LTBP4 | c.4130G>C p.C1377S (on ENST00000308370 / NM_001042544.1; = p.C1340S on NM_003573.2) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99180463; called by muse, mutect2, varscan2
- LYPD6 | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100493346; called by muse, mutect2
- MACROD2 | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99427188; called by muse, varscan2
- MAGI1 | c.4081C>T p.R1361C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV100439387; called by muse, mutect2, varscan2
- MAGI2 | c.2933T>A p.V978E | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100832954; called by muse, mutect2, varscan2
- MATN2 | c.1552A>C p.S518R | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.506); catalogued as COSV99645699; called by muse, mutect2, varscan2
- MGAM | c.4557G>C p.W1519C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101527380; called by muse, mutect2, varscan2
- MIA3 | c.4618C>A p.Q1540K | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV100484809, COSV60509608; called by muse, mutect2, varscan2
- MROH2B | c.816G>C p.L272F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV101270486; called by muse, mutect2
- MYO10 | c.4160G>A p.R1387K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as rs752205357, COSV99944745; called by muse, mutect2, varscan2
- NEGR1 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV100747167; called by muse, mutect2, varscan2
- NLGN3 | c.866T>C p.I289T (on ENST00000358741 / NM_181303.2; = p.I269T on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.029); catalogued as COSV100704553; called by muse, mutect2, varscan2
- NMUR1 | c.769C>G p.R257G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100531805, COSV59404998; called by muse, mutect2, varscan2
- NPAS3 | c.238C>G p.L80V (on ENST00000356141 / NM_001164749.2; = p.L50V on NM_022123.3) | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV100386151, COSV100387664; called by muse, mutect2, varscan2
- NPY | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV99635672; called by muse, varscan2
- NRDC | c.230G>C p.R77P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.969); catalogued as COSV100703096; called by muse, mutect2, varscan2
- NRXN1 | c.3865G>A p.A1289T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV100639824; called by muse, mutect2, varscan2
- NSD1 | c.5909A>C p.E1970A | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100728438; called by muse, mutect2, varscan2
- NSMAF | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV50685127; called by muse, mutect2, varscan2
- OR10K2 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV100149387, COSV59222515; called by muse, mutect2, varscan2
- OR2M2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs561993914, COSV100677180, COSV62899272; called by muse, mutect2, varscan2
- OR4A16 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100125024, COSV59043678; called by muse, mutect2, varscan2
- OR4C6 | c.418T>A p.C140S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.232); catalogued as COSV100051410, COSV99041498; called by muse, mutect2, varscan2
- OR4Q3 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100056907, COSV59180246; called by muse, mutect2, varscan2
- OR51G2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as rs750568250, COSV58992987; called by muse, mutect2, varscan2
- OR5AS1 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.081); catalogued as rs1291549525, COSV100546161; called by muse, mutect2, varscan2
- OR5M11 | c.685T>G p.S229A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101602018; called by muse, mutect2, varscan2
- OR5W2 | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs768884574, COSV100747541; called by muse, mutect2, varscan2
- PASK | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV52150526, COSV99300362; called by muse, mutect2, varscan2
- PCDH15 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV100215476; called by muse, mutect2, varscan2
- PCDH7 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.946); catalogued as COSV100687558; called by muse, mutect2
- PCLO | c.10452G>T p.M3484I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100427551; called by muse, mutect2, varscan2
- PDE10A | c.1944G>A p.M648I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs769165353, COSV100604478; called by muse, mutect2, varscan2
- PHOSPHO1 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56799090, COSV99865232; called by muse, mutect2
- PIGB | c.1544G>A p.S515N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99380040; called by muse, mutect2, varscan2
- PKHD1 | c.2128A>T p.T710S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.169); catalogued as COSV100581151; called by muse, mutect2, varscan2
- PKHD1L1 | c.5630C>T p.P1877L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV101005420, COSV101006689; called by muse, mutect2, varscan2
- PKHD1L1 | c.8102G>A p.G2701E | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV65739130; called by muse, mutect2, varscan2
- PLCL2 | c.1440T>A p.N480K (on ENST00000615277 / NM_001144382.2; = p.N354K on NM_015184.5) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV101196576; called by muse, mutect2, varscan2
- PLRG1 | c.792T>G p.C264W | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100122979; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- POLR1F | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99748620; called by muse, mutect2, varscan2
- POM121L12 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV101374845; called by muse, mutect2
- PON2 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99749369; called by muse, mutect2, varscan2
- PPP1R26 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100777992; called by muse, mutect2, varscan2
- PRDM9 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1462462836, COSV99689802; called by muse, mutect2, varscan2
- PREP | c.-151A>G | Splice Region (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100963723; called by muse, mutect2
- PRR19 | c.13G>T p.G5* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV56624047; called by muse, mutect2, varscan2
- PSG11 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 152/556 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs374837741; called by muse, mutect2, varscan2
- PTPRD | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100643398; called by muse, mutect2, varscan2
- RALGAPA2 | c.1386G>C p.E462D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as COSV99173154; called by muse, mutect2, varscan2
- RBFOX1 | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100299681; called by muse, mutect2, varscan2
- RECQL4 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.255); catalogued as COSV99466962; called by muse, mutect2, varscan2
- RP1 | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55111347, COSV99606302; called by muse, mutect2, varscan2
- RPL39L | c.25A>T p.I9F | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV99961499; called by muse, mutect2, varscan2
- RUFY2 | c.253A>T p.M85L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.819); catalogued as COSV100700067; called by muse, mutect2, varscan2
- RUNX1T1 | c.1760C>G p.T587S (on ENST00000265814 / NM_001198628.1; = p.T560S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99749570; called by muse, mutect2, varscan2
- RUNX1T1 | c.1234C>A p.H412N (on ENST00000265814 / NM_001198628.1; = p.H385N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV99749577; called by muse, mutect2, varscan2
- SCEL | c.731C>A p.S244* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100582601, COSV62994543; called by muse, mutect2, varscan2
- SCG3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV55020321; called by muse, mutect2
- SCN2A | c.3916A>G p.R1306G | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99330178; called by muse, mutect2, varscan2
- SEMA5A | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs959604188; called by muse, mutect2
- SGIP1 | c.101A>C p.Q34P | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99390532; called by muse, mutect2, varscan2
- SH3BP4 | c.1599G>T p.R533S | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100748999; called by muse, mutect2, varscan2
- SH3BP4 | c.1796C>A p.A599D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.058); catalogued as COSV100749001; called by muse, mutect2, varscan2
- SMC4 | c.1824del p.K608Nfs*15 | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | catalogued as rs1038263749; called by mutect2, varscan2
- SRSF5 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV99384180; called by muse, mutect2, varscan2
- SVEP1 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100237217; called by muse, mutect2, varscan2
- SYNE1 | c.26210G>A p.G8737D (on ENST00000367255 / NM_182961.4; = p.G8689D on NM_033071.3) | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54935271, COSV99578787; called by muse, mutect2, varscan2
- SYNPO2 | c.1502G>C p.R501T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100204788, COSV100204901; called by muse, mutect2, varscan2
- TCHH | c.2513A>T p.E838V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.415); catalogued as rs376051941; called by muse, mutect2, varscan2
- TENM1 | c.3711C>A p.H1237Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV99058425; called by muse, mutect2, varscan2
- THSD7A | c.656G>C p.R219P | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101448547, COSV101448565; called by muse, mutect2, varscan2
- TMPRSS15 | c.2487-2A>T p.X829_splice | Splice Site (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99516913; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3961G>T p.E1321* | Nonsense Mutation (SNP) | VAF 53/367 reads (14%) | catalogued as COSV100835802; called by muse, mutect2, varscan2
- TNR | c.1131G>C p.W377C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.7); catalogued as COSV99687685; called by muse, mutect2, varscan2
- TNR | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99687689; called by muse, mutect2, varscan2
- TNRC6C | c.3569G>A p.R1190H | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs890143714, COSV56944051; called by muse, mutect2
- TRIL | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs748581791, COSV100538730; called by muse, mutect2, varscan2
- TUBGCP2 | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV99427221; called by muse, mutect2, varscan2
- UGT2A3 | c.1364T>G p.L455R | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99279617; called by muse, mutect2, varscan2
- UNC5A | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.388); catalogued as COSV99457852; called by muse, mutect2, varscan2
- USH2A | c.14407A>G p.I4803V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764945259, COSV100229225; called by muse, mutect2, varscan2
- VEGFC | c.599C>A p.T200K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99709471; called by muse, mutect2, varscan2
- VPS13B | c.7595T>C p.M2532T | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1563913361, COSV100660891; called by muse, mutect2, varscan2
- VPS13D | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.55); catalogued as rs1472578988; called by muse, mutect2
- VWA3B | c.3431C>A p.P1144H | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV101417771; called by muse, mutect2
- WDR72 | c.2989G>T p.V997F | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100854215; called by muse, mutect2, varscan2
- YY1AP1 | c.1466C>T p.P489L (on ENST00000295566 / NM_139118.2; = p.P432L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.341); catalogued as rs370230805; called by muse, mutect2, varscan2
- ZBTB8A | c.778T>A p.Y260N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.436); catalogued as rs148974909, COSV100331299; called by muse, mutect2, varscan2
- ZNF404 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.133); catalogued as COSV100182305; called by muse, mutect2, varscan2
- ZNF417 | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV100364085; called by muse, mutect2, varscan2
- ZNF479 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs782473333, COSV100482487; called by muse, mutect2, varscan2
- ZNF565 | c.1208A>T p.Y403F (on ENST00000355114; = p.Y363F on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as COSV100411700, COSV100411776; called by muse, mutect2, varscan2
- ZNF572 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100073801, COSV100073948; called by muse, mutect2, varscan2
- ZNF676 | c.549C>A p.C183* (on ENST00000650058; = p.C151* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV101236100, COSV68092329; called by muse, mutect2, varscan2
- ZNF701 | c.1451T>A p.V484D (on ENST00000301093; = p.V418D on NM_018260.3) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as rs758783954, COSV56523525, COSV99990679; called by muse, mutect2, varscan2
- ZNF710 | c.1706A>G p.H569R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99184083; called by muse, mutect2, varscan2
- ZPLD1 | c.1167_1169del p.L390del (on ENST00000466937 / NM_001329788.1; = p.L406del on NM_175056.2) | In Frame Del (DEL) | VAF 28/212 reads (13%) | catalogued as rs1280615575; called by pindel, varscan2
- AATF | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CTNND2 | c.1627dup p.R543Kfs*27 | Frame Shift Ins (INS) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
- FAT2 | c.1633dup p.E545Gfs*15 | Frame Shift Ins (INS) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- MRC1 | c.3808C>G p.L1270V | Missense Mutation (SNP) | VAF 166/398 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- NEIL1 | c.15del p.E6Sfs*9 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- PKD2L1 | c.2088del p.R697Efs*28 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- SLC16A5 | c.49del p.L17Cfs*6 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- TRAV14DV4 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ZBTB7A | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACKR2 | c.315C>G p.S105= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV56180894, COSV99825359; called by muse, mutect2, varscan2
- AKAP10 | c.1122C>T p.T374= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99855269; called by muse, mutect2, varscan2
- ATP13A5 | c.2920C>T p.L974= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as rs766248821, COSV100664759; called by muse, mutect2, varscan2
- BAIAP2L1 | c.660C>A p.S220= | Silent (SNP) | VAF 44/220 reads (20%) | catalogued as COSV99133676; called by muse, mutect2, varscan2
- BRCA2 | c.2052G>A p.Q684= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV101203946; called by muse, mutect2, varscan2
- BTN2A1 | c.1176G>T p.V392= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as COSV100438381; called by muse, mutect2, varscan2
- CACNA1E | c.351G>A p.K117= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100701289; called by muse, mutect2, varscan2
- CD70 | c.535C>A p.R179= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99835515; called by muse, mutect2
- CHIT1 | c.756G>A p.Q252= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs1384555216, COSV99705046; called by muse, mutect2
- CNTN5 | c.2065C>T p.L689= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV99673059; called by muse, mutect2
- COL4A4 | c.462A>G p.R154= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV100306238; called by muse, mutect2, varscan2
- CORIN | c.2766T>C p.P922= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99902919; called by muse, mutect2, varscan2
- CR1L | c.1479T>C p.D493= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV99686813; called by muse, mutect2, varscan2
- CTCF | c.438C>A p.G146= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV99864401, COSV99864707; called by muse, mutect2, varscan2
- DCXR | c.363C>T p.G121= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs368246980, COSV100178798; called by muse, mutect2, varscan2
- DDX25 | c.1275T>C p.Y425= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99699659; called by muse, mutect2, varscan2
- DGKK | c.1635G>C p.L545= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV101052884; called by muse, mutect2, varscan2
- DYNC1H1 | c.2463G>A p.A821= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs764740993, COSV64137676; ClinVar: likely benign; called by muse, mutect2, varscan2
- EBF1 | c.1353A>G p.S451= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs1423079766, COSV100565171; called by muse, mutect2, varscan2
- EDA2R | c.633C>A p.T211= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as COSV99490510; called by muse, mutect2, varscan2
- FBXL13 | c.2115T>A p.P705= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV100501179; called by muse, mutect2, varscan2
- GSTA2 | c.165G>T p.V55= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV101534028; called by muse, mutect2, varscan2
- GUCY1A2 | c.1596C>A p.A532= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99972825; called by muse, mutect2, varscan2
- IGSF1 | c.649C>T p.L217= | Silent (SNP) | VAF 37/60 reads (62%) | catalogued as COSV100811833; called by muse, mutect2, varscan2
- LYPD6 | c.153C>G p.T51= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100493288, COSV100493347; called by muse, mutect2
- MAPT | c.1119C>G p.P373= (on ENST00000262410 / NM_001377265.1; = p.P298= on NM_016835.4) | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs762689602, COSV99289766; called by muse, mutect2, varscan2
- MCC | c.573G>A p.Q191= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV101342712; called by muse, mutect2, varscan2
- MSC | c.9G>A p.T3= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs1194257624, COSV100335572; called by muse, mutect2, varscan2
- MYF5 | c.555C>A p.I185= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV57355482, COSV99953128; called by muse, mutect2, varscan2
- MYO18A | c.4614C>T p.A1538= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV100571938; called by muse, mutect2, varscan2
- NCKAP1L | c.2514G>A p.R838= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV99514489; called by muse, mutect2, varscan2
- NPAS3 | c.2676T>C p.A892= (on ENST00000356141 / NM_001164749.2; = p.A860= on NM_022123.3) | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- NRSN1 | c.222C>A p.I74= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV65893799; called by muse, mutect2, varscan2
- OR12D2 | c.75C>T p.L25= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs765880896, COSV101011108; called by muse, mutect2, varscan2
- OR5B2 | c.861C>A p.V287= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV56907609; called by muse, mutect2, varscan2
- OR5R1 | c.432G>T p.L144= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV56573017; called by muse, mutect2, varscan2
- OR8J1 | c.96G>C p.L32= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100274870; called by muse, mutect2, varscan2
- PCDHA13 | c.1929G>C p.P643= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV99165049; called by muse, mutect2, varscan2
- PRR27 | c.177C>A p.V59= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV100748755; called by muse, mutect2, varscan2
- RIF1 | c.666A>G p.A222= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs148830532; called by muse, mutect2, varscan2
- RIMS2 | c.1365G>T p.R455= (on ENST00000666250 / NM_001348490.2; = p.R263= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV99160835; called by muse, mutect2, varscan2
- ROR2 | c.1311C>A p.S437= | Silent (SNP) | VAF 48/91 reads (53%) | catalogued as COSV65221045; called by muse, mutect2, varscan2
- RYR1 | c.4632C>T p.N1544= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs570920139, COSV100614524; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.9045C>T p.V3015= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100768072; called by muse, mutect2, varscan2
- SLC34A2 | c.1629G>T p.T543= | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as COSV101158222, COSV101158256; called by muse, mutect2, varscan2
- ST18 | c.2268A>G p.K756= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1271309923, COSV99388266; called by muse, mutect2, varscan2
- TAS2R38 | c.906C>T p.A302= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs781933600, COSV101516338; called by muse, mutect2, varscan2
- TEP1 | c.7719G>A p.K2573= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs755124344, COSV99401676; called by muse, mutect2, varscan2
- TMOD3 | c.681A>T p.T227= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV100419017; called by muse, mutect2, varscan2
- TRAV17 | c.249C>T p.V83= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- UIMC1 | c.1587G>A p.E529= | Silent (SNP) | VAF 65/242 reads (27%) | catalogued as COSV101022035; called by muse, mutect2, varscan2
- VPS4A | c.84G>T p.A28= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV99651828, COSV99652058; called by muse, mutect2, varscan2
- YOD1 | c.847C>T p.L283= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs1558053774, COSV100262849; called by muse, mutect2, varscan2
- ZNF462 | c.6351C>A p.I2117= | Silent (SNP) | VAF 160/446 reads (36%) | catalogued as COSV52931466, COSV99470822; called by muse, mutect2, varscan2
- C20orf197 | n.348C>A | RNA (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- GGT7 | c.1725+363G>C | Intron (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100321746; called by muse, mutect2, varscan2
- IGKV1-13 | n.141C>A | RNA (SNP) | VAF 41/184 reads (22%) | catalogued as rs1259921471; called by muse, mutect2, varscan2
- MIR297 | n.21C>T | RNA (SNP) | VAF 13/45 reads (29%) | catalogued as rs765617048; called by muse, mutect2
